Surgical pathology report (de-identified scan), TCGA case TCGA-BS-A0TI, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University of Hawaii, specimen TCGA-BS-A0TI-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology Report

Patient Name: [REDACTED]	Client: [REDACTED]	Accession #
Med Rec No: [REDACTED]	Location: [REDACTED]	Taken:
DOB: [REDACTED]	Pt. Phone no	Received:
Gender: F		Reported:
Physician(s): [REDACTED]		
cc:		

History/Clinical Dx: Endometrial cancer

Postoperative Dx: Same, pending pathology examination

Specimen(s) Received:

- A: Uterus, cervix, tubes and ovaries
- B: Left pelvic lymph node
- C: Left aortic lymph node
- D: Right pelvic lymph node
- E: Right aortic lymph node

100-0-3
adenocarcinoma, endometrioid, NOS 8380/3
Site: Endometrium C54.1 lw
10/27/11

DIAGNOSIS:

A. Uterus, cervix, tubes and ovaries: **ENDOMETRIAL ADENOCARCINOMA**

Tumor Information:

Operative procedure:	TAH-BSO with staging
Histologic type:	Endometrioid
Histologic grade(FIGO):	Grade 3
Nuclear grade:	2
Tumor size:	3.0 cm
Extent of invasion:	Greater than 50% of myometrial thickness (23mm invasion, myometrial thickness of 25mm)
Lympho/vascular invasion:	Present
Serosa:	Free of tumor
Parametrium:	Free of tumor
Cervical involvement:	Absent
Right adnexa:	Free of tumor
Left adnexa:	Free of tumor
Special studies:	On request
Staging information:	T1c, N0

- | | |
|------------------------------|---|
| B. Left pelvic lymph nodes: | Eight lymph nodes negative for metastasis (0/8) |
| C. Left aortic lymph node: | One lymph node negative for metastasis (0/1) |
| D. Right pelvic lymph nodes: | Six lymph nodes negative for metastasis (0/6) |
| E. Right aortic lymph nodes: | Three lymph nodes negative for metastasis (0/3) |

Pathology Report
The following information is provided for the purpose of the report. It is not intended to be a substitute for the clinical history or the results of other tests. The pathologist is not responsible for the interpretation of the results of this report. The pathologist is not responsible for the interpretation of the results of this report. The pathologist is not responsible for the interpretation of the results of this report.

[page 2 of 3]
Surgical Pathology Report

Gross Description

- A Received in formalin labeled [REDACTED] uterus, cervix, bilateral fallopian tubes and ovaries" is a previously opened uterus and cervix and attached right and left fallopian tubes and ovaries, 67.0 grams. The uterus is symmetrical in configuration, 5.0 cm in length, 3.5 cm in broadest extent, and up to 2.5 cm anterior-posteriorly. The cervical portion is 2.5 x 2.5 x 2.5 cm, and appears grossly normal. Situated along the anterior aspect of the endometrial canal an exophytic tumor mass, yellow-tan in color, with focal necrotic softening, 3.0 x 1.5 cm across. The cut surface of the tumor reveals it to grossly extend to a depth of 2.0 cm within the myometrium. By gross evaluation, the tumor is free of the outer serosal surface by a distance of 0.2 cm. At this level, the myometrium is 2.5 cm in thickness. The right and left fallopian tubes are unremarkable. The right and left ovaries are each approximately 2.5 x 1.5 x 1.0 cm, and contain several corpora albicantia. A portion of each ovary has been removed intraoperatively and submitted for cancer research. Representative sections, blocks A1-A11.

KEY TO CASSETTES:

- A1-A2 - Cervix
- A3 - Upper cervical canal
- A4-A7 - Tumor
- A8 - Right adnexa
- A9 - Left adnexa
- A10 - Right parametrium
- A11 - Left parametrium

- B. Received in formalin labeled [REDACTED], left pelvic lymph node" is a fragment of yellow-tan fatty soft tissue, 4.0 grams, 2.5 x 1.5 x 0.5 cm. By palpation and cross sectioning, there are multiple pink-tan rubbery lymphoid nodules, 1.0 cm in greatest dimension. Entirely submitted, blocks B1-B3.

KEY TO CASSETTES:

- B1 - Two lymph nodes
- B2 - Three lymph nodes
- B3 - Remainder of sample

- C. Received in formalin labeled [REDACTED] left aortic lymph node" is a fragment of yellow-tan fatty soft tissue, 1.0 grams, 1.0 x 1.0 x 0.5 cm. By palpation and cross sectioning, there is a pink-tan rubbery lymphoid nodule, 1.0 cm in greatest dimension. Entirely submitted, block C.

- D. Received in formalin labeled [REDACTED] right pelvic lymph node" is a fragment of yellow-tan fatty soft tissue, 6.0 grams, 3.5 x 2.5 x 1.5 cm. By palpation and cross sectioning, there are multiple soft pink-tan rubbery lymphoid nodules, 2.0 cm in greatest dimension. Entirely submitted, blocks D1-D4.

KEY TO CASSETTES:

- D1 - One lymph node
- D2 - Two lymph nodes
- D3 - Three lymph nodes
- D4 - Remainder of sample

- E. Received in formalin labeled [REDACTED] right aortic lymph node" is a fragment of yellow-tan fatty soft tissue, 1.0 grams, 1.5 x 1.0 x 0.5 cm. By palpation and cross sectioning, there are multiple pink-tan rubbery lymphoid nodules, 1.0 cm in greatest dimension. Entirely submitted, blocks E1-E2.

KEY TO CASSETTES:

- E1 - Three lymph nodes
- E2 - Remainder of sample

Microscopic Description

The microscopic findings support the above diagnosis.

[page 3 of 3]
Surgical Pathology Report

Source: NCI Genomic Data Commons file 7b3b9894-c5ec-4629-b084-fc8328b96be7 (TCGA-BS-A0TI.60212550-2757-4AB0-B778-723AE046F6BE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).